Gene-level copy-number profile of tumor specimen TCGA-61-1911-01A from TCGA case TCGA-61-1911, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 55.2 years (20,144 days).
Specimen TCGA-61-1911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.47a40c55-6066-499f-a0ab-127555f66481.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1911-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44401c22-ce0e-4e93-8d00-ab73418ab240

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,586; copy number 2: 36,670; copy number 3: 12,726; copy number 4: 2,722; copy number 5: 1,590; copy number 6: 10; copy number 7: 256; copy number 8: 122; copy number 10: 39; copy number 11: 55; copy number 13: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1911-01A-01D-0577-01): tumor purity 0.72, ploidy 2.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,522,666–181,591,969, 2 genes: AC093840.1, AC093840.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,111 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–237,833,988, 1 gene, copy number 5 (within-gene range 4–5): RYR2.
- chr1:237,471,119–239,250,818, 24 genes, copy number 5: MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1.
- chr3:41,246,599–44,122,365, 65 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:54,057,690–61,251,459, 86 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:63,741,827–72,279,503, 98 genes, copy number 5 (within-gene range 2–8) (broad region; genes not listed).
- chr3:72,371,825–75,435,110, 45 genes, copy number 5: RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP.
- chr3:75,446,769–75,491,202, 1 gene, copy number 5 (within-gene range 3–5): ENPP7P2.
- chr3:91,356,755–100,695,479, 101 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:101,163,094–108,222,435, 75 genes, copy number 5 (broad region; genes not listed).
- chr3:118,488,876–118,491,760, 1 gene, copy number 5: AC068633.2.
- chr3:120,596,328–132,874,223, 293 genes, copy number 5 (broad region; genes not listed).
- chr3:135,925,891–136,197,241, 7 genes, copy number 5: AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6.
- chr3:136,336,236–136,752,403, 1 gene, copy number 7 (within-gene range 4–7): STAG1.
- chr3:136,609,050–157,046,129, 350 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr3:159,902,045–187,449,450, 446 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr3:189,829,922–198,222,513, 211 genes, copy number 5–7 (broad region; genes not listed).
- chr8:100,509,752–100,683,574, 5 genes, copy number 6: ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P.
- chr11:76,349,956–80,528,066, 75 genes, copy number 5–10 (broad region; genes not listed).
- chr17:70,166,961–70,180,044, 2 genes, copy number 6: KCNJ2-AS1, KCNJ2.
- chr19:9,323,772–10,074,135, 38 genes, copy number 7 (within-gene range 4–7): ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT, ZNF121, ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589.
- chr19:20,340,269–20,424,969, 1 gene, copy number 5 (within-gene range 4–5): ZNF826P.
- chr19:20,389,658–24,077,377, 160 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:47,348,137–47,412,327, 3 genes, copy number 6: AL031666.3, AL031666.1, LINC01754.
- chr22:20,198,729–20,495,844, 22 genes, copy number 7: AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5.

Autosomal genes at a single copy (total copy number 1): 3,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
